Somatic mutation profile of tumor specimen TCGA-SR-A6MS-01A (aliquot TCGA-SR-A6MS-01A-11D-A35I-08) from TCGA case TCGA-SR-A6MS, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 35.5 years (12,979 days).
Specimen TCGA-SR-A6MS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 784f06cb-79e8-4f1e-b6d0-4a1fdbf1b066.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SR-A6MS-10A (Blood Derived Normal), aliquot TCGA-SR-A6MS-10A-01D-A35G-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f131947e-dd32-4a98-b4b4-41cbf455d684

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AOPEP | c.1762A>G p.K588E (on ENST00000375315 / NM_001193329.1; = p.K489E on NM_032823.5) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POPDC3 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RINL | c.1566C>G p.S522= (on ENST00000591812 / NM_001195833.2; = p.S408= on NM_198445.4) | Silent (SNP) | VAF 47/122 reads (39%) | catalogued as rs369751216, COSV61575296; called by muse, mutect2, varscan2
- TTLL6 | c.1026G>A p.L342= (on ENST00000393382 / NM_001130918.3; = p.L35= on NM_173623.3) | Silent (SNP) | VAF 27/73 reads (37%) | called by muse, mutect2, varscan2
